Somatic mutation profile of tumor specimen C3L-01237-04 (aliquot CPT0199820006) from CPTAC case C3L-01237, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 57.4 years (20,956 days).
Specimen C3L-01237-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 398d7255-b411-49b2-b42d-b6951d32ac90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01237-31 (Blood Derived Normal), aliquot CPT0200410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec6d5239-1ea4-4e05-b5e4-1b23cda0ab82

The open-access MAF lists 162 somatic variants for this specimen: 115 protein-altering or splice-affecting, 33 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 33, Intron 7, Nonsense Mutation 7, Frame Shift Del 4, RNA 4, Frame Shift Ins 4, 5'UTR 1, 5'Flank 1, Translation Start Site 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.487T>A p.Y163N | Missense Mutation (SNP) | VAF 228/439 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANKRD33B | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as rs1001545039; called by muse, mutect2, varscan2
- BEGAIN | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.057); catalogued as rs774868143, COSV62070156; called by muse, mutect2, varscan2
- C1R | c.1000A>G p.I334V (on ENST00000536053 / NM_001354346.2; = p.I320V on NM_001733.7) | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.013); catalogued as rs376786076; called by muse, varscan2
- C1orf116 | c.1682A>T p.Y561F | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV100847917; called by muse, mutect2, varscan2
- CEP350 | c.1501A>G p.I501V | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1383645774; called by muse, mutect2, varscan2
- CNST | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.587); catalogued as rs148030749; called by muse, mutect2, varscan2
- CYP3A5 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs1374335261; called by muse, mutect2
- EPHA4 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as rs777531997, COSV99915784; called by muse, mutect2, varscan2
- ERCC5 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99958713; called by muse, mutect2, varscan2
- FANCF | c.53C>G p.S18* | Nonsense Mutation (SNP) | VAF 71/612 reads (12%) | catalogued as COSV59417175; called by muse, mutect2, varscan2
- FAT4 | c.4151C>G p.S1384C | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV101272525; called by muse, mutect2, varscan2
- FRMPD3 | c.4942C>T p.R1648C | Missense Mutation (SNP) | VAF 125/266 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750187969; called by muse, mutect2, varscan2
- HHIPL2 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1327717850, COSV100596615; called by muse, mutect2
- KREMEN2 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 91/425 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs1188343628; called by muse, mutect2
- LAMA3 | c.3250C>G p.L1084V | Missense Mutation (SNP) | VAF 105/848 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs771066828; called by muse, mutect2, varscan2
- LRRTM4 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV69139877; called by muse, mutect2
- MARK3 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs183634888, COSV53505818, COSV53509981; called by muse, mutect2, varscan2
- MC5R | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201046123; called by muse, mutect2, varscan2
- NAV2 | c.6163G>A p.D2055N (on ENST00000396087 / NM_001244963.2; = p.D1996N on NM_145117.5) | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1240265876, COSV60659578; called by muse, mutect2, varscan2
- NCOR1 | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV51960790; called by muse, mutect2, varscan2
- NOL4 | c.650C>G p.S217* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV52344900; called by muse, mutect2
- OBSCN | c.3217A>T p.M1073L | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV52833188; called by muse, mutect2, varscan2
- ONECUT2 | c.1286C>G p.S429C | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV72153038, COSV72153046; called by muse, mutect2, varscan2
- OR4A15 | c.175T>C p.F59L | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.144); catalogued as rs749271641, COSV59036475; called by muse, mutect2, varscan2
- PCDH15 | c.4951G>T p.E1651* | Nonsense Mutation (SNP) | VAF 103/366 reads (28%) | catalogued as COSV64673604; called by muse, mutect2, varscan2
- PCDH8 | c.2259C>G p.I753M | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1247581887; called by muse, mutect2, varscan2
- PEPD | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 96/579 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV104390151; called by muse, mutect2, varscan2
- POM121L12 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 2002/2213 reads (90%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV68692577; called by muse, mutect2, varscan2
- PPP2R5D | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 161/475 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.011); catalogued as rs780858279, COSV55144364; called by muse, mutect2, varscan2
- RBM33 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 55/436 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1213477635, COSV56635462; called by muse, mutect2, varscan2
- REEP2 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.558); catalogued as rs1330664969; ClinVar: uncertain significance; called by muse, mutect2
- RESF1 | c.2236G>C p.E746Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57026448; called by muse, mutect2, varscan2
- RSAD1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV99364258; called by muse, mutect2, varscan2
- SSNA1 | c.91C>G p.R31G | Missense Mutation (SNP) | VAF 66/376 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1382912705; called by muse, mutect2, varscan2
- SUGP2 | c.2848C>T p.R950W | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764583773, COSV58265938; called by muse, mutect2
- TMTC4 | c.158A>G p.N53S (on ENST00000376234 / NM_001350577.2; = p.N72S on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs892458584; called by muse, mutect2, varscan2
- TRIM36 | c.1720C>T p.H574Y | Missense Mutation (SNP) | VAF 79/452 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1307936869, COSV56694063; called by muse, mutect2, varscan2
- TTN | c.28687G>A p.E9563K (on ENST00000591111; = p.E8636K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/122 reads (19%) | PolyPhen possibly damaging (0.555); catalogued as rs532933900, COSV59982346; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VSTM4 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100251414, COSV60528871; called by muse, mutect2, varscan2
- ZAN | c.1364A>G p.H455R | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as rs748344261; called by muse, mutect2, varscan2
- ATAD2 | c.2566A>G p.I856V | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.412); called by muse, varscan2
- BRD1 | c.2635G>T p.A879S (on ENST00000216267 / NM_001349940.1; = p.A1010S on NM_001304808.3) | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C1orf68 | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 76/538 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CAPRIN1 | c.516G>C p.L172F | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- CCDC154 | c.1869G>T p.M623I | Missense Mutation (SNP) | VAF 84/532 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP68 | c.443_486del p.D148Gfs*96 | Frame Shift Del (DEL) | VAF 68/640 reads (11%) | called by mutect2, pindel
- CFTR | c.2140G>A p.V714M | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CHD6 | c.1816A>G p.R606G | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- COL6A3 | c.8227C>A p.L2743M | Missense Mutation (SNP) | VAF 58/676 reads (9%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.971); called by muse, mutect2
- COL6A3 | c.8226G>A p.M2742I | Missense Mutation (SNP) | VAF 57/678 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.696); called by muse, mutect2
- CPNE3 | c.1267C>T p.L423F | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- CTSO | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2
- CUL9 | c.2282A>T p.K761M | Missense Mutation (SNP) | VAF 170/549 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CYRIB | c.59del p.F20Sfs*20 | Frame Shift Del (DEL) | VAF 22/226 reads (10%) | called by mutect2, pindel, varscan2
- DDHD1 | c.1739C>T p.S580L (on ENST00000323669; = p.S777L on NM_030637.3) | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DDX60L | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2
- EDIL3 | c.996C>G p.D332E | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- EIF2B2 | c.-27_7del | Translation Start Site (DEL) | VAF 128/908 reads (14%) | called by mutect2, pindel
- EPHA1 | c.419C>G p.P140R | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC3 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 159/581 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERN2 | c.1465A>T p.R489W | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); called by muse, mutect2
- FAM161A | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.077); called by mutect2, varscan2
- FAM205A | c.856T>C p.F286L | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- FAM83B | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- FBXO25 | c.270T>A p.H90Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2
- GAPVD1 | c.556dup p.S186Ffs*2 | Frame Shift Ins (INS) | VAF 82/320 reads (26%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2
- GCN1 | c.4470G>C p.L1490F | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GEMIN4 | c.1126G>T p.V376F | Missense Mutation (SNP) | VAF 75/294 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- HCCS | c.760G>C p.A254P | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HECA | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.05); called by muse, mutect2
- HLTF | c.1447C>A p.P483T | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-42 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IQGAP3 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- KCNE4 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2
- LAMA1 | c.5518_5564del p.K1840Gfs*17 | Frame Shift Del (DEL) | VAF 46/568 reads (8%) | called by mutect2, pindel
- LINGO1 | c.1631C>A p.T544N | Missense Mutation (SNP) | VAF 95/537 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- MAP2 | c.5446G>A p.E1816K | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MDGA2 | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 131/581 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- MED13 | c.5989A>T p.I1997F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MIS18BP1 | c.87C>G p.I29M | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- MRRF | c.130T>C p.Y44H | Missense Mutation (SNP) | VAF 125/349 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTSS2 | c.1838A>T p.E613V | Missense Mutation (SNP) | VAF 87/633 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NBEAL1 | c.1598G>C p.R533T | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- OR2F1 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARD6A | c.1039dup p.*347Lfs*? | Frame Shift Ins (INS) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- PDK4 | c.886G>C p.G296R | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHKB | c.3067G>C p.D1023H | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, varscan2
- PIK3C2G | c.1311dup p.C438Mfs*18 | Frame Shift Ins (INS) | VAF 19/86 reads (22%) | called by mutect2, pindel, varscan2
- PLPP2 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 30/560 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- PLXND1 | c.5664C>G p.I1888M | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, varscan2
- PRDM5 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 66/581 reads (11%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- PRDM6 | c.1026C>G p.Y342* | Nonsense Mutation (SNP) | VAF 51/177 reads (29%) | called by muse, mutect2, varscan2
- PRSS56 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PTPRC | c.2956C>G p.P986A | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RC3H1 | c.545_558del p.N182Sfs*4 | Frame Shift Del (DEL) | VAF 95/379 reads (25%) | called by mutect2, pindel, varscan2
- RGS9 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 141/639 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SAFB | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SBK2 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.027); called by muse, mutect2
- SBK2 | c.581C>A p.P194Q | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- SLCO1C1 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- SMIM17 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 35/454 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); called by muse, mutect2
- SOX3 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 222/482 reads (46%) | called by muse, mutect2, varscan2
- SRCAP | c.9331G>A p.V3111I | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SUN2 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 128/534 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- TF | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 143/660 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- UNC13C | c.3561A>T p.E1187D | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- USP31 | c.894G>C p.Q298H | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- VIRMA | c.76A>G p.I26V | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF322 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | called by mutect2, varscan2
- ZNF41 | c.1895A>G p.E632G | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF43 | c.1262C>A p.T421N | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ZNF462 | c.3186G>C p.R1062S | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ZNF7 | c.234dup p.T79Dfs*9 | Frame Shift Ins (INS) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- ANK1 | c.3594C>T p.N1198= | Silent (SNP) | VAF 100/918 reads (11%) | catalogued as rs186020985; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARFIP2 | c.168G>T p.G56= | Silent (SNP) | VAF 83/243 reads (34%) | called by muse, mutect2, varscan2
- BOP1 | c.42C>T p.S14= | Silent (SNP) | VAF 62/408 reads (15%) | called by muse, mutect2, varscan2
- COL3A1 | c.465T>C p.Y155= | Silent (SNP) | VAF 106/474 reads (22%) | called by muse, mutect2, varscan2
- COMMD9 | c.190C>T p.L64= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV54673621; called by muse, mutect2, varscan2
- CYP7B1 | c.1305G>A p.L435= | Silent (SNP) | VAF 21/176 reads (12%) | called by muse, mutect2, varscan2
- DCAF5 | c.159C>T p.F53= | Silent (SNP) | VAF 66/345 reads (19%) | called by muse, mutect2, varscan2
- DICER1 | c.3324C>T p.I1108= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as rs765205680; ClinVar: likely benign; called by muse, mutect2
- DNAJC6 | c.324A>G p.V108= | Silent (SNP) | VAF 37/147 reads (25%) | called by muse, mutect2, varscan2
- DOCK2 | c.2667C>G p.L889= | Silent (SNP) | VAF 46/243 reads (19%) | catalogued as COSV56952058; called by muse, mutect2, varscan2
- DOP1A | c.2454G>T p.V818= | Silent (SNP) | VAF 48/1253 reads (4%) | called by muse, mutect2
- DPAGT1 | c.858C>T p.F286= | Silent (SNP) | VAF 62/415 reads (15%) | called by muse, mutect2, varscan2
- DSP | c.4494A>G p.K1498= | Silent (SNP) | VAF 203/601 reads (34%) | catalogued as rs1182511839; called by muse, mutect2, varscan2
- INSRR | c.3579C>T p.Y1193= | Silent (SNP) | VAF 106/491 reads (22%) | called by muse, mutect2, varscan2
- KCNB2 | c.240T>C p.Y80= | Silent (SNP) | VAF 39/124 reads (31%) | called by muse, mutect2, varscan2
- KSR1 | c.156C>T p.I52= | Silent (SNP) | VAF 82/714 reads (11%) | catalogued as rs780147912; called by muse, mutect2, varscan2
- LRRC4C | c.1065G>A p.V355= | Silent (SNP) | VAF 70/195 reads (36%) | catalogued as rs149409879; called by muse, mutect2, varscan2
- MAP3K6 | c.996G>A p.A332= | Silent (SNP) | VAF 39/220 reads (18%) | catalogued as rs552134673, COSV62888730; called by muse, mutect2, varscan2
- MINAR1 | c.1554C>T p.I518= | Silent (SNP) | VAF 36/167 reads (22%) | called by muse, mutect2, varscan2
- NEIL3 | c.1698G>A p.L566= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs1441469817; called by muse, mutect2, varscan2
- PCDH11X | c.3729C>T p.L1243= | Silent (SNP) | VAF 139/624 reads (22%) | called by muse, mutect2, varscan2
- PCLO | c.10251T>A p.A3417= | Silent (SNP) | VAF 73/319 reads (23%) | called by muse, mutect2, varscan2
- PCLO | c.981G>A p.G327= | Silent (SNP) | VAF 41/312 reads (13%) | catalogued as COSV61649287; called by muse, mutect2, varscan2
- PTPRC | c.2508G>A p.R836= | Silent (SNP) | VAF 142/543 reads (26%) | called by muse, mutect2, varscan2
- SMPD4 | c.906C>G p.L302= | Silent (SNP) | VAF 50/358 reads (14%) | catalogued as COSV100302719; called by muse, mutect2, varscan2
- SOX14 | c.444C>T p.A148= | Silent (SNP) | VAF 119/454 reads (26%) | called by muse, mutect2, varscan2
- STK17B | c.339T>A p.A113= | Silent (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2
- UFSP2 | c.1029A>G p.T343= | Silent (SNP) | VAF 33/269 reads (12%) | catalogued as rs1205496266; called by muse, mutect2, varscan2
- VSTM2A | c.273G>A p.P91= | Silent (SNP) | VAF 29/960 reads (3%) | called by muse, mutect2
- ZBTB39 | c.1377A>G p.V459= | Silent (SNP) | VAF 35/205 reads (17%) | catalogued as rs914099299; called by muse, mutect2, varscan2
- ZC3HC1 | c.852C>T p.F284= | Silent (SNP) | VAF 77/263 reads (29%) | called by muse, mutect2, varscan2
- ZNF71 | c.1326G>A p.Q442= | Silent (SNP) | VAF 56/604 reads (9%) | called by muse, mutect2
- ZNF786 | c.1809C>T p.R603= | Silent (SNP) | VAF 62/434 reads (14%) | catalogued as rs1201629232; called by muse, mutect2, varscan2
- AC021218.1 | n.558C>G | RNA (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2819G>C | Intron (SNP) | VAF 8/40 reads (20%) | catalogued as rs1372292089; called by muse, mutect2, varscan2
- DNAH2 | c.1904+88C>T | Intron (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- GPX3 | c.87+118G>A | Intron (SNP) | VAF 14/121 reads (12%) | catalogued as rs774153009; called by muse, mutect2
- MAEA | c.656+934G>A | Intron (SNP) | VAF 11/37 reads (30%) | catalogued as rs756801761; called by muse, mutect2, varscan2
- MIR651 | n.76G>C | RNA (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- OR51F5P | n.142C>T | RNA (SNP) | VAF 71/308 reads (23%) | called by muse, mutect2, varscan2
- PLEKHM1P1 | n.1698C>T | RNA (SNP) | VAF 81/534 reads (15%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49892791 T>G | 5'Flank (SNP) | VAF 179/556 reads (32%) | called by muse, mutect2, varscan2
- SP5 | c.-13G>T | 5'UTR (SNP) | VAF 152/654 reads (23%) | called by muse, mutect2, varscan2
- SPDL1 | c.160-276C>T | Intron (SNP) | VAF 37/208 reads (18%) | catalogued as rs1365388982; called by muse, mutect2, varscan2
- SRP9 | c.142-193A>G | Intron (SNP) | VAF 32/146 reads (22%) | called by muse, mutect2
- TCEA1 | c.127-2876C>T | Intron (SNP) | VAF 67/281 reads (24%) | called by muse, mutect2, varscan2
- Unknown | chr21:16071203 G>A | IGR (SNP) | VAF 66/277 reads (24%) | called by muse, mutect2, varscan2
